Somatic mutation profile of tumor specimen ALCH-B20I-TTP1-A (aliquot ALCH-B20I-TTP1-A-1-0-D-A773-36) from ALCHEMIST case ALCH-B20I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.1 years (28,161 days).
Specimen ALCH-B20I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad7ab52e-f703-4293-9823-55a99f495992.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B20I-NB1-A (Blood Derived Normal), aliquot ALCH-B20I-NB1-A-1-0-D-A773-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dd108a2-457e-4bcd-b7af-eb4b655e3450

The open-access MAF lists 197 somatic variants for this specimen: 140 protein-altering or splice-affecting, 36 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 36, Intron 10, Nonsense Mutation 10, Splice Site 5, RNA 5, 3'UTR 4, Frame Shift Del 4, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 39/187 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CIC | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 12/167 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50554428; called by muse, mutect2
- ADAM21 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs766690661; called by muse, mutect2
- ADGRB1 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs768708980; called by muse, mutect2, varscan2
- AL121899.2 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs187614014; called by muse, mutect2, varscan2
- ANO5 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 59/602 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV100201520; called by muse, mutect2, varscan2
- APLN | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs372284454; called by muse, mutect2, varscan2
- CD163 | c.3297G>T p.M1099I | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.914); catalogued as COSV63128994; called by muse, mutect2
- CHAT | c.1151G>T p.C384F | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1385019490; called by muse, mutect2, varscan2
- CUL9 | c.5881C>T p.R1961W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs763218615; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs754135731; called by mutect2, varscan2*
- DNAH12 | c.7153G>A p.D2385N (on ENST00000351747; = p.D3253N on NM_001366028.2) | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.451); catalogued as rs373886381; called by muse, mutect2
- EPHA3 | c.2691-1G>T p.X897_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | catalogued as COSV60728445; called by muse, varscan2
- EYS | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 39/398 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs1258209665; ClinVar: uncertain significance; called by muse, mutect2
- FAP | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51863485; called by muse, mutect2, varscan2
- FBF1 | c.881C>T p.T294I (on ENST00000586717; = p.T308I on NM_001319193.1) | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204995313; called by muse, mutect2, varscan2
- FLNB | c.4939A>T p.K1647* | Nonsense Mutation (SNP) | VAF 31/190 reads (16%) | catalogued as COSV55870039; called by muse, mutect2, varscan2
- FLNC | c.6565G>A p.E2189K | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV100367464; called by muse, mutect2
- KEAP1 | c.399G>C p.M133I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV50270536; called by muse, mutect2, varscan2
- KLK4 | c.476-7G>A | Splice Region (SNP) | VAF 24/189 reads (13%) | catalogued as rs377181928, COSV100133621; called by muse, mutect2, varscan2
- LAMB1 | c.2868C>A p.D956E | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.081); catalogued as COSV55970082; called by muse, mutect2
- MEIS2 | c.1092G>T p.Q364H (on ENST00000561208 / NM_170675.5; = p.Q344H on NM_002399.3) | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54943206; called by muse, mutect2, varscan2
- MROH1 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760290051, COSV58191306; called by muse, mutect2, varscan2
- MRPL13 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs145547223; called by muse, mutect2, varscan2
- MUC16 | c.35825C>A p.T11942N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.509); catalogued as COSV67473226; called by muse, mutect2, varscan2
- NAALAD2 | c.1796C>G p.A599G | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100428580; called by muse, mutect2, varscan2
- NANOG | c.913G>T p.V305L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745903026; called by mutect2, varscan2
- NBAS | c.5333C>G p.A1778G | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.103); catalogued as COSV55737738; called by muse, mutect2, varscan2
- NLRP11 | c.229C>A p.R77S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.154); catalogued as COSV64085396, COSV64088549; called by muse, mutect2
- NYNRIN | c.4270C>G p.L1424V | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV66841203; called by muse, mutect2, varscan2
- OR2W3 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64457105; called by muse, mutect2, varscan2
- OR4D2 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200607563, COSV73459699; called by muse, mutect2, varscan2
- OR52I2 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 59/536 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144837372; called by muse, mutect2, varscan2
- PANK2 | c.1553T>C p.V518A (on ENST00000316562 / NM_153638.3; = p.V227A on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs752169196; called by muse, mutect2, varscan2
- PARP10 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782238694; called by muse, mutect2
- PCLO | c.12899G>T p.G4300V | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100428040; called by muse, mutect2, varscan2
- POLR2A | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100495415; called by muse, mutect2, varscan2
- PPP2R1B | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs997026408; called by muse, mutect2
- PRSS12 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs758938961, COSV99628956; called by muse, mutect2
- REG3A | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs138199548; called by muse, mutect2, varscan2
- RHCG | c.1113-2A>C p.X371_splice | Splice Site (SNP) | VAF 7/56 reads (13%) | catalogued as COSV51517076; called by muse, mutect2
- RYR2 | c.6261G>C p.L2087F | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63674287; called by muse, mutect2, varscan2
- RYR2 | c.10702G>T p.V3568L | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV63692075; called by muse, mutect2, varscan2
- SH2D4A | c.777G>T p.R259S | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56122530; called by muse, mutect2, varscan2
- SLAMF7 | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100833284; called by muse, mutect2, varscan2
- SLC12A8 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58871670; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 62/293 reads (21%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- TRDN | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs760549842, COSV100523656, COSV62116193; called by muse, mutect2
- TRGC2 | c.495T>G p.S165R | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754313372; called by muse, mutect2, varscan2
- TRPM2 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV55968884, COSV55973022; called by muse, mutect2, varscan2
- VPS37A | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs755402438, COSV61365503; called by muse, mutect2, varscan2
- ACSM5 | c.712A>T p.K238* | Nonsense Mutation (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- ADAMDEC1 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- ADAMTS3 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.196); called by muse, mutect2
- AHSG | c.38T>G p.L13R | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANO4 | c.1235G>A p.S412N (on ENST00000392977 / NM_001286615.2; = p.S377N on NM_178826.4) | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATP9B | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CA5A | c.626G>C p.R209P | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CACNA1B | c.2417G>T p.R806L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- CCDC150 | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, varscan2
- CDH26 | c.2410C>A p.Q804K (on ENST00000348616 / NM_177980.4; = p.Q137K on NM_021810.6) | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CGGBP1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.274); called by muse, mutect2
- COL1A2 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 87/722 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CUBN | c.730A>T p.S244C | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- DLGAP2 | c.349_350del p.R117Afs*238 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by pindel, varscan2
- EMCN | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- EPB41L3 | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EPHA8 | c.1868G>A p.G623D | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ETV5 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXL7 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- FCRL1 | c.320-1G>T p.X107_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | called by muse, varscan2
- FNDC1 | c.4067G>A p.W1356* | Nonsense Mutation (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- GABRB1 | c.1035C>A p.D345E | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT12 | c.930G>T p.M310I | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- GALNT12 | c.953G>C p.S318T | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, varscan2
- GLRX5 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- GPR3 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- HBM | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- HOXD11 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IFNA4 | c.59G>C p.C20S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- IPCEF1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- KBTBD6 | c.837dup p.G280Rfs*17 | Frame Shift Ins (INS) | VAF 16/116 reads (14%) | called by mutect2, varscan2
- KIF14 | c.4471C>T p.Q1491* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- KIF24 | c.172A>T p.I58F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLF14 | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- KLHL13 | c.379A>G p.M127V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- KRTAP5-5 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- LIG1 | c.1217G>C p.S406T | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRCH3 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, varscan2
- LRFN5 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 46/344 reads (13%) | called by muse, mutect2, varscan2
- LRP2 | c.5129G>A p.S1710N | Missense Mutation (SNP) | VAF 84/441 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- LRRC47 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by mutect2, varscan2
- MARK1 | c.2360C>G p.S787* | Nonsense Mutation (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- MEPCE | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2
- MGAM2 | c.4252A>G p.M1418V | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MINDY3 | c.1123A>T p.S375C | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MYH10 | c.4529G>C p.R1510P | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NCF2 | c.824A>G p.D275G | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLGN1 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 66/606 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLN | c.992A>G p.E331G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- NOTCH2 | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 39/380 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OLFM4 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- OR14K1 | c.81G>T p.L27F | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2M7 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- OR2W3 | c.330_331del p.E111Vfs*10 | Frame Shift Del (DEL) | VAF 47/230 reads (20%) | called by mutect2, pindel, varscan2
- OR8K1 | c.310G>C p.A104P | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- OTOL1 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PATE1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB4 | c.1691C>A p.A564E | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- PCNX3 | c.5304G>T p.M1768I | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PCSK2 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCB1 | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- PLCG2 | c.3110T>A p.V1037D | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2
- PNLIPRP1 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- PODN | c.822C>G p.S274R (on ENST00000395871; = p.S226R on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- PP2D1 | c.1757_1760del p.T586Rfs*16 | Frame Shift Del (DEL) | VAF 30/282 reads (11%) | called by mutect2, pindel
- PPP4R3C | c.1180A>T p.S394C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PSMB11 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RASL10B | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); called by muse, mutect2
- RIC8B | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- ROBO2 | c.1519+1G>T p.X507_splice | Splice Site (SNP) | VAF 37/344 reads (11%) | called by muse, mutect2, varscan2
- RPGR | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SELL | c.887C>A p.S296Y (on ENST00000650983; = p.S283Y on NM_000655.5) | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC28A1 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SOAT2 | c.1387A>T p.M463L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSBP2 | c.1057-2A>G p.X353_splice | Splice Site (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- STXBP5L | c.584T>C p.M195T | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TENM3 | c.6011T>A p.I2004N | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFPI | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM225 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNXB | c.137A>T p.H46L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TTC17 | c.3144G>T p.Q1048H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- UBR4 | c.14422G>T p.G4808C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC45B | c.1531G>C p.A511P | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VASH2 | c.617C>T p.S206L (on ENST00000517399 / NM_001301056.2; = p.S162L on NM_024749.5) | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2
- VWC2 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- WDR64 | c.2571C>A p.F857L | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZFHX4 | c.125G>T p.R42M | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- ZNF157 | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- ZNF318 | c.5351G>A p.R1784K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- AAK1 | c.2796G>T p.G932= | Silent (SNP) | VAF 75/259 reads (29%) | called by muse, mutect2, varscan2
- AMOTL2 | c.1476G>T p.A492= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as rs569708164; called by muse, mutect2, varscan2
- BTNL9 | c.1332G>T p.V444= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1170572008; called by muse, mutect2, varscan2
- C4orf54 | c.822G>A p.P274= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs1054483508; called by muse, mutect2, varscan2
- CCSER1 | c.2034G>T p.S678= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs373571745, COSV100389979, COSV100397877; called by muse, varscan2
- CDH10 | c.2124G>T p.T708= | Silent (SNP) | VAF 95/379 reads (25%) | catalogued as COSV100052096, COSV52573235; called by muse, mutect2, varscan2
- CNTN6 | c.1728C>T p.L576= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100611987, COSV63170502; called by muse, mutect2, varscan2
- DPP4 | c.834A>T p.S278= | Silent (SNP) | VAF 36/280 reads (13%) | called by muse, varscan2
- EFCAB10 | c.321T>C p.D107= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs200413293; called by muse, mutect2, varscan2
- EML6 | c.585G>T p.G195= | Silent (SNP) | VAF 51/237 reads (22%) | called by muse, mutect2, varscan2
- EXT1 | c.549G>A p.L183= | Silent (SNP) | VAF 61/498 reads (12%) | called by muse, mutect2, varscan2
- FAT4 | c.6243A>T p.P2081= | Silent (SNP) | VAF 24/304 reads (8%) | called by muse, mutect2
- FKBP15 | c.1242G>T p.P414= | Silent (SNP) | VAF 34/345 reads (10%) | called by muse, mutect2
- GABRB3 | c.652C>T p.L218= | Silent (SNP) | VAF 112/498 reads (22%) | catalogued as rs75829834; called by muse, mutect2, varscan2
- GREB1L | c.1170G>C p.L390= | Silent (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- GSK3B | c.306A>G p.R102= | Silent (SNP) | VAF 55/223 reads (25%) | called by muse, mutect2, varscan2
- IGKV1D-39 | c.18C>T p.P6= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs1373249760; called by mutect2, varscan2
- ISL1 | c.792C>T p.P264= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV100045635, COSV57932686; called by muse, mutect2
- JARID2 | c.84G>T p.V28= | Silent (SNP) | VAF 19/196 reads (10%) | called by muse, mutect2, varscan2
- KCNH8 | c.1641A>G p.L547= | Silent (SNP) | VAF 32/249 reads (13%) | called by muse, mutect2, varscan2
- KDM4C | c.1716C>A p.R572= | Silent (SNP) | VAF 32/335 reads (10%) | catalogued as rs368924481; called by muse, mutect2, varscan2
- KERA | c.573C>A p.L191= | Silent (SNP) | VAF 27/273 reads (10%) | called by muse, mutect2, varscan2
- MS4A14 | c.42C>A p.I14= | Silent (SNP) | VAF 19/170 reads (11%) | called by muse, varscan2
- MUC16 | c.9564G>T p.T3188= | Silent (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- NLRC5 | c.5020C>T p.L1674= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- OR2G3 | c.837C>A p.T279= | Silent (SNP) | VAF 33/177 reads (19%) | catalogued as COSV60682846; called by muse, mutect2, varscan2
- OR2T4 | c.819C>T p.C273= | Silent (SNP) | VAF 65/530 reads (12%) | catalogued as COSV63544050; called by muse, mutect2
- OR51E2 | c.447C>A p.V149= | Silent (SNP) | VAF 31/290 reads (11%) | called by muse, mutect2, varscan2
- OR52J3 | c.288T>C p.Y96= | Silent (SNP) | VAF 61/332 reads (18%) | catalogued as rs375135865; called by muse, mutect2, varscan2
- OTOGL | c.1191G>T p.R397= (on ENST00000547103; = p.R388= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/178 reads (6%) | catalogued as rs1212087291, COSV72007279; called by muse, mutect2
- PCDHA7 | c.324G>A p.V108= | Silent (SNP) | VAF 56/292 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.2151G>A p.R717= | Silent (SNP) | VAF 33/188 reads (18%) | catalogued as rs1055854699; called by muse, mutect2, varscan2
- PITPNM1 | c.1671G>T p.G557= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV62709591; called by mutect2, varscan2
- PSMB11 | c.531G>T p.V177= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99943977; called by muse, mutect2
- SLIT2 | c.2091G>T p.L697= | Silent (SNP) | VAF 37/225 reads (16%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1863C>A p.V621= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV65674664; called by muse, mutect2, varscan2
- AC002511.3 | n.325-85G>T | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- AGBL5 | c.2242+34C>G | Intron (SNP) | VAF 40/265 reads (15%) | called by muse, mutect2, varscan2
- AL353753.1 | n.248G>T | RNA (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- DENND3 | c.3396+148G>T | Intron (SNP) | VAF 29/161 reads (18%) | called by muse, mutect2, varscan2
- GUSBP10 | n.253G>C | RNA (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- HPRT1 | c.-81G>T | 5'UTR (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2
- IL18R1 | c.-11G>A | 5'UTR (SNP) | VAF 10/106 reads (9%) | catalogued as COSV99294928; called by mutect2, varscan2
- INPP4B | c.2643-1341G>T | Intron (SNP) | VAF 23/218 reads (11%) | called by muse, mutect2, varscan2
- KIF28P | n.2723G>A | RNA (SNP) | VAF 26/390 reads (7%) | catalogued as rs542794337; called by muse, mutect2
- LINC01630 | n.122G>T | RNA (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- MIR216B | n.61G>T | RNA (SNP) | VAF 59/197 reads (30%) | called by muse, mutect2, varscan2
- MYBL2 | c.*51del | 3'UTR (DEL) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- NRSN1 | c.190-4555C>A | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- SCN4B | c.62-97A>G | Intron (SNP) | VAF 43/280 reads (15%) | catalogued as rs998283380; called by muse, mutect2, varscan2
- SLC35E2B | c.762-62G>T | Intron (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*4T>C | 3'UTR (SNP) | VAF 29/135 reads (21%) | catalogued as COSV100085954; called by muse, varscan2
- TPM3 | c.642+537A>T | Intron (SNP) | VAF 42/520 reads (8%) | called by muse, mutect2
- TRDN | c.484+1205G>A | Intron (SNP) | VAF 21/264 reads (8%) | catalogued as COSV62119912; called by muse, mutect2
- UMPS | c.*1737C>A | 3'UTR (SNP) | VAF 68/287 reads (24%) | called by muse, mutect2, varscan2
- VCP | c.130-32A>G | Intron (SNP) | VAF 36/239 reads (15%) | catalogued as rs371847371; called by muse, mutect2, varscan2
- ZNF521 | c.*1T>G | 3'UTR (SNP) | VAF 36/286 reads (13%) | called by muse, mutect2, varscan2
